Somatic mutation profile of tumor specimen TCGA-18-3410-01A (aliquot TCGA-18-3410-01A-01D-0983-08) from TCGA case TCGA-18-3410, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 81.7 years (29,827 days).
Specimen TCGA-18-3410-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8bf5099e-5cba-45a1-b55e-838db49cdfe8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-18-3410-11A (Solid Tissue Normal), aliquot TCGA-18-3410-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bac7d711-99ca-41dd-a9ef-f31d4930fa23

The open-access MAF lists 218 somatic variants for this specimen: 170 protein-altering or splice-affecting, 42 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 42, Nonsense Mutation 9, Frame Shift Del 5, Splice Region 4, Intron 3, RNA 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.637C>G p.R213G | Missense Mutation (SNP) | VAF 11/21 reads (52%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABAT | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51623491; called by muse, mutect2, varscan2
- ABCC6 | c.792G>C p.R264= | Splice Region (SNP) | VAF 21/71 reads (30%) | catalogued as COSV52743945; called by muse, mutect2, varscan2
- ACAD8 | c.730C>T p.R244* | Nonsense Mutation (SNP) | VAF 6/16 reads (38%) | catalogued as rs746960051, COSV55540453, COSV55542140; ClinVar: uncertain significance; called by mutect2, varscan2
- AFAP1L1 | c.1675G>A p.D559N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV57045281; called by mutect2, varscan2
- AGBL2 | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs1197495441, COSV100101504, COSV54092129; called by muse, mutect2, varscan2
- AMZ1 | c.302T>C p.I101T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV56686821; called by muse, mutect2, varscan2
- ANKAR | c.1838A>G p.Y613C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772172022, COSV55612848; called by muse, mutect2, varscan2
- ANO1 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 69/1356 reads (5%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs768725000, COSV60282850, COSV60284696; called by muse, mutect2
- AP1B1 | c.2439G>A p.Q813= | Splice Region (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100434728, COSV58017629; called by muse, mutect2, varscan2
- ARHGEF16 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs536938385, COSV65682005; called by muse, mutect2, varscan2
- ATP1A2 | c.1650G>T p.L550= | Splice Region (SNP) | VAF 19/41 reads (46%) | catalogued as rs775807326, COSV63403793; called by muse, mutect2, varscan2
- ATP6V1A | c.1604A>G p.Y535C | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as rs758773602, COSV56362294; called by muse, mutect2, varscan2
- ATP8B4 | c.1377G>C p.M459I | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52715716, COSV99466908; called by muse, mutect2, varscan2
- BCAT2 | c.31G>T p.A11S | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV60272513; called by muse, mutect2, varscan2
- BDP1 | c.7441C>G p.P2481A | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV62431448, COSV62434626; called by muse, mutect2, varscan2
- BSDC1 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV61982045; called by muse, mutect2, varscan2
- C1orf54 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV64859598; called by mutect2, varscan2
- C2CD5 | c.385G>C p.D129H | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV61723769, COSV61724619; called by muse, mutect2, varscan2
- CACNG7 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.076); catalogued as COSV55814503; called by muse, mutect2
- CCDC113 | c.561G>C p.E187D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV54686069; called by muse, mutect2, varscan2
- CCDC125 | c.242G>A p.S81N | Missense Mutation (SNP) | VAF 73/128 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as rs745542923, COSV67288085; called by muse, mutect2, varscan2
- CCDC150 | c.672G>T p.K224N | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.224); catalogued as rs1393128059, COSV55874399; called by muse, mutect2, varscan2
- CCDC185 | c.1801C>G p.P601A | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64820871; called by muse, mutect2, varscan2
- CCDC47 | c.1419G>C p.M473I | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56723058; called by muse, mutect2, varscan2
- CDCP2 | c.375C>G p.F125L | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.914); catalogued as COSV61283881; called by muse, mutect2, varscan2
- CDH8 | c.554C>T p.S185F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV54867820; called by muse, mutect2, varscan2
- CGNL1 | c.535A>G p.T179A | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV55567875; called by muse, mutect2, varscan2
- CKLF-CMTM1 | c.168C>G p.I56M | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753659189, COSV50451287; called by muse, mutect2, varscan2
- CLOCK | c.1291T>G p.S431A | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as COSV59401940; called by muse, mutect2, varscan2
- CMPK1 | c.411C>G p.N137K | Missense Mutation (SNP) | VAF 29/61 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV64101901; called by muse, mutect2, varscan2
- COL6A6 | c.4010C>T p.A1337V | Missense Mutation (SNP) | VAF 90/223 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV62025428; called by muse, mutect2, varscan2
- CRYGA | c.229C>A p.Q77K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58016764; called by muse, mutect2, varscan2
- CYP11B2 | c.911T>C p.I304T | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1220548229, COSV59995924; called by muse, mutect2, varscan2
- DENND4A | c.1671G>A p.M557I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV71265855; called by muse, mutect2, varscan2
- DNAH8 | c.7632G>C p.Q2544H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59445796; called by muse, mutect2, varscan2
- DNAH9 | c.9437G>A p.C3146Y | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758754444, COSV52349987; called by muse, mutect2, varscan2
- DNAI3 | c.1651C>G p.P551A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as COSV54002569; called by muse, mutect2, varscan2
- EHF | c.752A>G p.K251R | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV57668199; called by muse, mutect2, varscan2
- EIF3E | c.1221G>T p.K407N | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV55203028; called by muse, mutect2, varscan2
- EPHA5 | c.1710C>A p.S570R | Missense Mutation (SNP) | VAF 28/63 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV56645868; called by muse, mutect2, varscan2
- ESYT3 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV67440837; called by muse, mutect2, varscan2
- ETV3L | c.1074G>T p.L358F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.785); catalogued as COSV71901091; called by mutect2, varscan2
- EXOSC5 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54197166, COSV99524691; called by muse, mutect2, varscan2
- EXPH5 | c.2914G>C p.G972R | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.754); catalogued as COSV56202393; called by muse, mutect2, varscan2
- FAM214A | c.819G>A p.W273* | Nonsense Mutation (SNP) | VAF 19/59 reads (32%) | catalogued as COSV55924191; called by muse, mutect2, varscan2
- FAM83B | c.420del p.K141Rfs*2 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as COSV60928050; called by mutect2, pindel, varscan2
- FBXO27 | c.489G>C p.K163N | Missense Mutation (SNP) | VAF 36/202 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53072418, COSV99494806; called by muse, mutect2, varscan2
- FEM1C | c.146C>G p.A49G | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT tolerated (0.1); PolyPhen benign (0.32); catalogued as COSV57231578; called by muse, varscan2
- FREM2 | c.4100G>C p.G1367A | Missense Mutation (SNP) | VAF 27/42 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV54838017, COSV99748059; called by muse, mutect2, varscan2
- GLRX3 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58692695; called by muse, mutect2, varscan2
- GPX5 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 44/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69079411; called by muse, mutect2, varscan2
- GRHL3 | c.304C>A p.P102T (on ENST00000350501 / NM_198174.3; = p.P107T on NM_021180.3) | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV52566719, COSV52568338; called by muse, mutect2, varscan2
- GRIA4 | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.024); catalogued as COSV56896635; called by muse, mutect2, varscan2
- GRIN2A | c.871A>G p.R291G | Missense Mutation (SNP) | VAF 20/31 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58033254; called by muse, mutect2, varscan2
- GRM2 | c.1966C>A p.R656S | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56584923; called by muse, mutect2, varscan2
- HCN1 | c.2353C>A p.P785T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.058); catalogued as COSV57511193; called by muse, mutect2, varscan2
- HLA-B | c.956C>A p.A319E | Missense Mutation (SNP) | VAF 27/96 reads (28%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.609); catalogued as COSV69521353; called by muse, mutect2, varscan2
- HTT | c.5722C>G p.Q1908E | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.949); catalogued as COSV61862140; called by muse, mutect2, varscan2
- IBTK | c.2254A>G p.N752D | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV60392941; called by muse, mutect2, varscan2
- ING5 | c.679T>C p.W227R | Missense Mutation (SNP) | VAF 44/164 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV57978633; called by muse, mutect2, varscan2
- IPPK | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs148738677; called by muse, mutect2, varscan2
- IQCB1 | c.1658A>G p.H553R | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60437539; called by muse, mutect2, varscan2
- KCND2 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV58580365; called by muse, mutect2, varscan2
- LAMB4 | c.2799C>A p.S933R | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV52719556; called by muse, mutect2, varscan2
- LENG9 | c.1252C>G p.P418A | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.222); catalogued as COSV56618315; called by muse, mutect2, varscan2
- LRCH3 | c.1775C>G p.S592C | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV58392061; called by muse, varscan2
- LRP1B | c.7244A>T p.D2415V | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV67221189; called by muse, mutect2, varscan2
- LSG1 | c.731G>C p.G244A | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV54570272; called by muse, mutect2, varscan2
- MCC | c.2476G>C p.E826Q | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); catalogued as COSV56729032, COSV56729052; called by muse, mutect2, varscan2
- MLH3 | c.4138C>G p.L1380V (on ENST00000355774 / NM_001040108.2; = p.L1356V on NM_014381.3) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV53155213; called by muse, mutect2, varscan2
- MMP16 | c.1089G>C p.Q363H | Missense Mutation (SNP) | VAF 55/156 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as COSV54165471; called by muse, mutect2, varscan2
- MOAP1 | c.281A>G p.K94R | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.25); catalogued as COSV52092557; called by muse, mutect2, varscan2
- MOGAT1 | c.715C>A p.P239T | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.733); catalogued as COSV101485125, COSV71479894; called by mutect2, varscan2
- MTFR2 | c.649C>G p.Q217E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as COSV63079057; called by muse, varscan2
- MUC16 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.52); catalogued as COSV67448411, COSV67466519; called by muse, mutect2
- MYCBP2 | c.10039G>T p.D3347Y (on ENST00000357337; = p.D3385Y on NM_015057.5) | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV62019568; called by muse, mutect2, varscan2
- MYH8 | c.2421G>T p.M807I | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV67965254; called by muse, mutect2, varscan2
- NAV3 | c.2772G>A p.L924= | Splice Region (SNP) | VAF 28/194 reads (14%) | catalogued as COSV57080455; called by muse, varscan2
- NEK1 | c.1884G>T p.K628N | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV71456076; called by muse, mutect2, varscan2
- NET1 | c.389G>C p.R130T (on ENST00000355029 / NM_001047160.3; = p.R76T on NM_005863.5) | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV61791495; called by muse, mutect2, varscan2
- NFASC | c.2031C>A p.D677E (on ENST00000339876 / NM_001378329.1; = p.D673E on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.024); catalogued as COSV58365688; called by muse, mutect2, varscan2
- NINL | c.1711G>C p.E571Q | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV54002692; called by muse, mutect2, varscan2
- NLRP13 | c.1192C>A p.H398N | Missense Mutation (SNP) | VAF 50/102 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV61621732; called by muse, mutect2, varscan2
- NRAP | c.4948C>T p.Q1650* (on ENST00000359988 / NM_001322945.2; = p.Q1615* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV63490644, COSV63492932; called by muse, mutect2, varscan2
- NUCB1 | c.608A>T p.E203V | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); catalogued as COSV54386308; called by muse, mutect2, varscan2
- NUP43 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 91/174 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61189874; called by muse, mutect2, varscan2
- OR10G8 | c.506G>C p.G169A | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV70908556, COSV70908802; called by muse, mutect2, varscan2
- OR4C46 | c.471G>T p.Q157H | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.624); catalogued as rs1241710835, COSV60219417; called by muse, mutect2, varscan2
- OR5AC2 | c.703G>T p.G235C | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV62279516; called by muse, mutect2, varscan2
- OSBPL1A | c.1346C>T p.T449M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as rs1328441756, COSV60198392; called by mutect2, varscan2
- PAPPA2 | c.1754A>G p.N585S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.854); catalogued as COSV62776645, COSV62778345; called by muse, mutect2, varscan2
- PARP10 | c.1471C>T p.Q491* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as rs1322738588, COSV57297833; called by muse, mutect2, varscan2
- PCID2 | c.1167G>C p.Q389H | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV55813817; called by muse, mutect2, varscan2
- PDHA1 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 53/67 reads (79%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV63328164; called by muse, mutect2, varscan2
- PDZD2 | c.785A>G p.H262R | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs932790244, COSV56858508; called by muse, mutect2, varscan2
- PDZD2 | c.4660G>A p.D1554N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.019); catalogued as rs746582090, COSV56855072; called by muse, mutect2, varscan2
- PES1 | c.1343G>A p.G448E | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1035694104, COSV58828561; called by muse, mutect2, varscan2
- PES1 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58828565; called by muse, mutect2, varscan2
- PICALM | c.1358C>G p.S453* | Nonsense Mutation (SNP) | VAF 16/89 reads (18%) | catalogued as COSV100708287, COSV62670825; called by muse, mutect2, varscan2
- PLCE1 | c.1809G>T p.E603D | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53350820; called by muse, mutect2, varscan2
- PLCH1 | c.2290G>C p.E764Q (on ENST00000340059 / NM_001130960.2; = p.E776Q on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV58197415; called by muse, mutect2, varscan2
- PLD1 | c.2395G>A p.D799N | Missense Mutation (SNP) | VAF 31/302 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as rs540439098, COSV60568108; called by muse, mutect2
- POTEH | c.558G>C p.W186C | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.979); catalogued as COSV100625036; called by muse, varscan2
- POU2AF1 | c.420G>C p.L140F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV67577270; called by muse, mutect2, varscan2
- PRKCQ | c.334C>G p.Q112E | Missense Mutation (SNP) | VAF 43/176 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0.069); catalogued as COSV54111492; called by muse, mutect2, varscan2
- PRPF3 | c.438G>T p.M146I | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV61394820; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.891G>T p.M297I (on ENST00000352766; = p.M174I on NM_181334.5) | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV61233553; called by muse, mutect2, varscan2
- PSMD5 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.83); PolyPhen benign (0.173); catalogued as COSV99270854; called by muse, mutect2, varscan2
- PTGFR | c.29T>A p.V10E | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV66115041; called by muse, mutect2, varscan2
- PTPN22 | c.1232A>G p.K411R (on ENST00000359785 / NM_001193431.2; = p.K356R on NM_012411.5) | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as COSV63085109; called by muse, mutect2, varscan2
- PYGM | c.1948C>G p.R650G | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.987); catalogued as CM071957, HD080026, COSV51217236, COSV99377190; called by muse, mutect2, varscan2
- QRSL1 | c.1306G>C p.E436Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.555); catalogued as COSV64688739; called by muse, mutect2, varscan2
- RBMX2 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs373592866, COSV100564812, COSV59729244; called by muse, mutect2, varscan2
- RDH8 | c.569C>T p.A190V (on ENST00000651512; = p.A170V on NM_015725.4) | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as rs757302315, COSV50675044; called by muse, mutect2, varscan2
- RELN | c.218A>C p.E73A | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV59002618; called by muse, mutect2, varscan2
- REPS2 | c.554C>A p.T185K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV58182284; called by muse, mutect2, varscan2
- RNASEL | c.1312G>T p.E438* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as COSV62376847; called by muse, mutect2, varscan2
- RNF125 | c.208T>C p.W70R | Missense Mutation (SNP) | VAF 98/215 reads (46%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.998); catalogued as COSV54184950; called by muse, mutect2, varscan2
- RPP30 | c.703A>G p.R235G | Missense Mutation (SNP) | VAF 99/156 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs139597628; called by muse, mutect2, varscan2
- SCARA5 | c.1340G>C p.R447P | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV61572090, COSV61574497; called by muse, mutect2, varscan2
- SCGB2A1 | c.24G>A p.M8I | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV55276199; called by muse, mutect2, varscan2
- SEPTIN3 | c.542C>A p.T181K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.562); catalogued as COSV52172275; called by muse, mutect2, varscan2
- SERPINA7 | c.473T>A p.V158D | Missense Mutation (SNP) | VAF 81/106 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs770595393, COSV59665841, COSV59667529; called by muse, mutect2, varscan2
- SLC25A37 | c.376G>C p.E126Q | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51564149; called by muse, mutect2, varscan2
- SLC35G6 | c.869T>C p.V290A | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59492305; called by muse, mutect2, varscan2
- SLC39A3 | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as COSV54118042; called by muse, mutect2, varscan2
- SLC45A1 | c.1772C>G p.S591* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV57095450; called by muse, mutect2, varscan2
- SMCHD1 | c.3575C>G p.S1192C | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.338); catalogued as COSV55257541; called by muse, mutect2, varscan2
- SMG1 | c.7985A>G p.E2662G | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.34); PolyPhen benign (0.107); catalogued as COSV67171409; called by muse, mutect2, varscan2
- SPATA22 | c.646G>T p.D216Y | Missense Mutation (SNP) | VAF 38/56 reads (68%) | SIFT tolerated (1); PolyPhen possibly damaging (0.875); catalogued as COSV52152625; called by muse, mutect2, varscan2
- SSMEM1 | c.289C>T p.P97S | Missense Mutation (SNP) | VAF 34/91 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52833514; called by muse, mutect2, varscan2
- STIL | c.3180G>C p.L1060F | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54550262; called by muse, mutect2, varscan2
- SYDE2 | c.1438G>T p.A480S | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV52315603; called by muse, mutect2, varscan2
- SYT12 | c.1157A>G p.H386R | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); catalogued as COSV67354006; called by muse, mutect2, varscan2
- TACR3 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1233777799, COSV59199166, COSV59200810, COSV59201645; called by muse, mutect2, varscan2
- TAOK1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55591879; called by muse, mutect2, varscan2
- TAS1R1 | c.1339A>T p.S447C | Missense Mutation (SNP) | VAF 52/135 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV59839833; called by muse, mutect2, varscan2
- TBC1D19 | c.607G>T p.E203* | Nonsense Mutation (SNP) | VAF 13/74 reads (18%) | catalogued as COSV53516909; called by muse, mutect2, varscan2
- TBC1D9 | c.1116C>G p.I372M | Missense Mutation (SNP) | VAF 30/177 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV71307526; called by muse, mutect2, varscan2
- TLR4 | c.1448del p.F483Sfs*13 (on ENST00000355622 / NM_138554.5; = p.F443Sfs*13 on NM_003266.4) | Frame Shift Del (DEL) | VAF 29/59 reads (49%) | catalogued as COSV100842701, COSV62924271; called by mutect2, pindel, varscan2
- TMEM200C | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67309457, COSV67310145; called by muse, mutect2, varscan2
- TNS2 | c.3349C>G p.Q1117E (on ENST00000314250 / NM_170754.4; = p.Q1127E on NM_015319.2) | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56853885; called by muse, mutect2, varscan2
- TPCN1 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 75/184 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); catalogued as COSV59235353; called by muse, mutect2, varscan2
- TPTE | c.1629del p.S544Vfs*4 (on ENST00000618007 / NM_199261.4; = p.S526Vfs*4 on NM_199259.4) | Frame Shift Del (DEL) | VAF 7/68 reads (10%) | catalogued as rs759410796; called by mutect2, varscan2
- TRIOBP | c.2689C>T p.P897S | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.915); catalogued as COSV60377586; called by muse, mutect2, varscan2
- TRPC4AP | c.1915G>C p.E639Q | Missense Mutation (SNP) | VAF 66/160 reads (41%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.958); catalogued as rs369793283; called by muse, varscan2
- TRPC4AP | c.1848G>C p.Q616H | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV52679929; called by muse, varscan2
- TRPC5 | c.2045G>C p.C682S | Missense Mutation (SNP) | VAF 67/93 reads (72%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV53290735; called by muse, mutect2, varscan2
- TTN | c.39171C>G p.I13057M (on ENST00000591111; = p.I5633M on NM_003319.4) | Missense Mutation (SNP) | VAF 20/119 reads (17%) | PolyPhen probably damaging (0.997); catalogued as COSV60067040, COSV60381602; called by muse, mutect2, varscan2
- TWF2 | c.286C>G p.R96G | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV59726430; called by muse, mutect2, varscan2
- UBR5 | c.4916G>C p.R1639P | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as COSV55286983; called by muse, mutect2, varscan2
- UBXN2A | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV58336496; called by mutect2, varscan2
- UGT3A1 | c.1193T>A p.M398K | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV57098192; called by muse, mutect2, varscan2
- USP8 | c.631C>G p.Q211E | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV56164346; called by muse, mutect2, varscan2
- VPS13A | c.2964G>T p.K988N | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.947); catalogued as COSV62430061; called by muse, mutect2, varscan2
- YAF2 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.65); PolyPhen benign (0.013); catalogued as rs751838921, COSV59891235; called by muse, mutect2, varscan2
- ZEB1 | c.2713G>C p.A905P | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as COSV58044134; called by muse, mutect2, varscan2
- ZFHX4 | c.2155C>T p.Q719* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV50809233; called by muse, mutect2, varscan2
- ZFP28 | c.1897G>A p.A633T | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV56735896; called by muse, mutect2, varscan2
- ZKSCAN8 | c.64C>G p.L22V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV57638267; called by muse, mutect2, varscan2
- ZNF229 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 33/210 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as COSV52161946; called by muse, mutect2, varscan2
- ZNF462 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.146); catalogued as rs748823761, COSV52938515; called by mutect2, varscan2
- ZNF91 | c.607G>A p.V203I | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs369764933; called by mutect2, varscan2
- ZNF98 | c.407A>G p.K136R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs756369684, COSV63336618; called by mutect2, varscan2
- ZZZ3 | c.556G>T p.G186W | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.721); catalogued as COSV100890356; called by muse, mutect2, varscan2
- GGNBP2 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIP4K2C | c.285del p.S96Vfs*79 | Frame Shift Del (DEL) | VAF 45/148 reads (30%) | called by mutect2, pindel, varscan2
- TRAV12-1 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ZNF99 | c.1782del p.K594Nfs*20 | Frame Shift Del (DEL) | VAF 38/101 reads (38%) | called by mutect2, pindel, varscan2
- ABCC9 | c.1794C>G p.A598= | Silent (SNP) | VAF 18/68 reads (26%) | catalogued as COSV53971800; called by muse, varscan2
- ANK2 | c.3498A>T p.P1166= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV52161664; called by muse, mutect2, varscan2
- ARMT1 | c.9C>A p.V3= | Silent (SNP) | VAF 17/99 reads (17%) | catalogued as rs747216789, COSV66178565; called by muse, mutect2, varscan2
- ASNSD1 | c.72A>G p.L24= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs760935277, COSV53623748; called by muse, mutect2, varscan2
- BTLA | c.315G>C p.V105= | Silent (SNP) | VAF 59/172 reads (34%) | catalogued as COSV57938524; called by muse, mutect2, varscan2
- CALB2 | c.495G>A p.L165= | Silent (SNP) | VAF 60/83 reads (72%) | catalogued as COSV56939425, COSV56942422; called by muse, mutect2, varscan2
- CRYGA | c.228C>A p.V76= | Silent (SNP) | VAF 23/63 reads (37%) | catalogued as COSV58016767; called by muse, mutect2, varscan2
- DENND6B | c.654C>T p.S218= | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV69806942; called by muse, mutect2, varscan2
- DNAH7 | c.4902A>C p.L1634= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56765285; called by muse, mutect2, varscan2
- DNASE1L1 | c.684C>T p.R228= | Silent (SNP) | VAF 11/28 reads (39%) | catalogued as rs782064221, COSV50010057; called by muse, mutect2, varscan2
- FAM171B | c.2076G>C p.L692= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV59003573; called by muse, mutect2, varscan2
- FAM47A | c.675G>A p.P225= | Silent (SNP) | VAF 22/28 reads (79%) | catalogued as rs776044393, COSV60496205; called by muse, mutect2, varscan2
- FIP1L1 | c.1143C>G p.V381= | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- FNBP1 | c.654G>A p.E218= | Silent (SNP) | VAF 40/196 reads (20%) | catalogued as rs41279170, COSV63087535; called by muse, varscan2
- GLDC | c.867G>A p.L289= | Silent (SNP) | VAF 95/154 reads (62%) | catalogued as COSV58680146; called by muse, mutect2, varscan2
- GNPDA2 | c.810C>T p.F270= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV54946765; called by muse, mutect2, varscan2
- GPR158 | c.3645G>T p.V1215= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs1157522511, COSV66270472; called by muse, mutect2
- GRM6 | c.1974C>A p.G658= | Silent (SNP) | VAF 9/13 reads (69%) | catalogued as COSV51441424; called by muse, mutect2, varscan2
- GTF3C1 | c.3696G>A p.K1232= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as rs939997963, COSV100649522; called by muse, varscan2
- GUCY2F | c.2607C>G p.L869= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as COSV54302066; called by muse, mutect2, varscan2
- JAKMIP1 | c.2067C>T p.T689= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs1239397499, COSV68952800; called by muse, mutect2, varscan2
- LAP3 | c.837T>C p.F279= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as rs1167377948, COSV56899901; called by muse, mutect2, varscan2
- LMBR1L | c.924G>T p.V308= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV57267700; called by muse, mutect2, varscan2
- MACROD2 | c.108C>T p.P36= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs770733009, COSV53986124; called by muse, mutect2, varscan2
- MAP3K12 | c.126G>A p.L42= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV57232858; called by muse, varscan2
- MRPL32 | c.21C>G p.V7= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs751148668, COSV56237727; called by muse, mutect2, varscan2
- MYCT1 | c.315G>A p.Q105= | Silent (SNP) | VAF 90/147 reads (61%) | catalogued as COSV65891328, COSV65891747; called by muse, mutect2, varscan2
- NCOR2 | c.3297A>T p.P1099= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV62298169; called by muse, mutect2, varscan2
- NDUFAF7 | c.984A>T p.T328= | Silent (SNP) | VAF 21/72 reads (29%) | catalogued as COSV50017545; called by muse, mutect2, varscan2
- NUP155 | c.789C>T p.F263= (on ENST00000231498 / NM_153485.3; = p.F204= on NM_004298.4) | Silent (SNP) | VAF 12/94 reads (13%) | catalogued as COSV51527075; called by muse, mutect2, varscan2
- OR5M11 | c.207G>T p.V69= | Silent (SNP) | VAF 57/160 reads (36%) | catalogued as COSV73141765, COSV73142009; called by muse, mutect2, varscan2
- PSD3 | c.303C>T p.H101= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as rs752543857, COSV58968858; called by muse, mutect2, varscan2
- RBBP5 | c.1509C>G p.L503= | Silent (SNP) | VAF 32/80 reads (40%) | catalogued as COSV52704576; called by muse, mutect2, varscan2
- RIMS1 | c.3225A>G p.K1075= | Silent (SNP) | VAF 36/71 reads (51%) | catalogued as COSV53456464, COSV53459254; called by muse, mutect2
- RP1 | c.3357T>C p.S1119= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV55116905; called by muse, mutect2, varscan2
- TRIM49 | c.1152G>A p.K384= | Silent (SNP) | VAF 9/93 reads (10%) | catalogued as COSV61670844; called by muse, mutect2, varscan2
- UBAP2L | c.2214C>T p.T738= | Silent (SNP) | VAF 27/53 reads (51%) | catalogued as COSV55172819; called by muse, mutect2, varscan2
- URB2 | c.1854T>C p.A618= | Silent (SNP) | VAF 70/146 reads (48%) | catalogued as rs1476554281, COSV50991322; called by muse, mutect2, varscan2
- WDR90 | c.3915G>C p.S1305= | Silent (SNP) | VAF 35/52 reads (67%) | catalogued as COSV53469927, COSV53475139; called by muse, mutect2, varscan2
- ZNF229 | c.2208C>T p.G736= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs777593082, COSV52160763; called by muse, mutect2, varscan2
- ZNF585A | c.2280G>T p.V760= (on ENST00000292841 / NM_001288800.2; = p.V705= on NM_152655.3) | Silent (SNP) | VAF 25/117 reads (21%) | catalogued as COSV53063724; called by muse, mutect2, varscan2
- ZNF804B | c.795C>T p.C265= | Silent (SNP) | VAF 21/42 reads (50%) | catalogued as COSV60828444; called by muse, mutect2, varscan2
- AGAP7P | n.1431C>A | RNA (SNP) | VAF 18/90 reads (20%) | called by muse, mutect2, varscan2
- ANKRD13D | c.*1060G>T | 3'UTR (SNP) | VAF 25/88 reads (28%) | catalogued as COSV57384854; called by muse, mutect2, varscan2
- R3HDM1 | c.2047+4039G>C | Intron (SNP) | VAF 8/60 reads (13%) | catalogued as COSV51524859; called by muse, varscan2
- RIMS2 | c.4064-21167C>T | Intron (SNP) | VAF 10/20 reads (50%) | catalogued as COSV99173028; called by muse, mutect2, varscan2
- RPL10 | c.330-149C>T | Intron (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99186037; called by muse, mutect2, varscan2
- SPATA8 | n.909A>G | RNA (SNP) | VAF 40/91 reads (44%) | catalogued as rs1393816822, COSV60704681; called by muse, mutect2, varscan2
